Somatic mutation profile of tumor specimen C3L-04844-01 (aliquot CPT0248330006) from CPTAC case C3L-04844, project CPTAC-3 (Tonsil — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 61.0 years (22,268 days).
Specimen C3L-04844-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tonsil; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8655238-4eb3-44ab-a341-c77be602afa1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04844-31 (Blood Derived Normal), aliquot CPT0248360002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c37c044a-46b7-46e8-9374-9235ee63a195

The open-access MAF lists 389 somatic variants for this specimen: 246 protein-altering or splice-affecting, 82 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 208, Silent 82, Intron 33, Nonsense Mutation 26, RNA 11, 3'UTR 6, 5'Flank 5, 5'UTR 5, Splice Region 4, Frame Shift Del 3, Frame Shift Ins 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNJ11 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 112/189 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs587783672, CM071808, COSV60594125; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 21/146 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 160/448 reads (36%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANKAR | c.4063G>C p.E1355Q | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.11); catalogued as COSV51462186; called by muse, mutect2, varscan2
- ANKRD11 | c.3259_3261del p.K1087del | In Frame Del (DEL) | VAF 340/646 reads (53%) | catalogued as rs1443780328; called by pindel, varscan2
- ARID4B | c.3638A>G p.K1213R | Missense Mutation (SNP) | VAF 55/219 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as rs200039195; called by muse, mutect2, varscan2
- ARID5B | c.2316C>G p.I772M | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as rs1317226229; called by muse, mutect2
- BOD1L1 | c.5752G>A p.E1918K | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); catalogued as COSV50008203; called by muse, mutect2, varscan2
- C6 | c.1075G>C p.D359H | Missense Mutation (SNP) | VAF 96/311 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV54708278; called by muse, mutect2, varscan2
- CACNA1S | c.4591G>A p.E1531K | Missense Mutation (SNP) | VAF 92/592 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs765917408; called by muse, mutect2, varscan2
- CCDC85A | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 90/191 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775195592, COSV101339464, COSV68154085; called by muse, mutect2, varscan2
- CCL11 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 106/378 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.074); catalogued as COSV100005521; called by muse, mutect2, varscan2
- CERKL | c.1657G>C p.E553Q (on ENST00000339098 / NM_001030311.2; = p.E527Q on NM_201548.5) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs753367773, COSV59204284; called by muse, mutect2, varscan2
- CNTN6 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs375832321; called by muse, mutect2, varscan2
- COBL | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 93/316 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as COSV54340642; called by muse, mutect2, varscan2
- COL1A1 | c.359G>A p.R120Q | Missense Mutation (SNP) | VAF 157/450 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs35183627, COSV56808616; called by muse, mutect2, varscan2
- DCC | c.3986G>A p.R1329K | Missense Mutation (SNP) | VAF 128/493 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.63); catalogued as COSV71428594; called by muse, mutect2, varscan2
- DMD | c.6352C>T p.Q2118* | Nonsense Mutation (SNP) | VAF 66/260 reads (25%) | catalogued as CM098434, COSV100822077; called by muse, mutect2, varscan2
- DMD | c.2687C>A p.A896D | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.088); catalogued as COSV63766053; called by muse, mutect2, varscan2
- DNAJA4 | c.577C>T p.R193C (on ENST00000343789; = p.R222C on NM_018602.3) | Missense Mutation (SNP) | VAF 87/360 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.344); catalogued as rs752407072; called by muse, mutect2, varscan2
- EGF | c.677C>G p.S226C | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV54478103, COSV54481538; called by muse, mutect2, varscan2
- ELAPOR2 | c.947C>T p.S316F (on ENST00000450689 / NM_001142749.3; = p.S149F on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 79/346 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99789271; called by muse, mutect2, varscan2
- EMILIN1 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs751281575; called by muse, mutect2, varscan2
- EYA3 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 82/211 reads (39%) | catalogued as COSV65817047; called by muse, mutect2, varscan2
- FAM120AOS | c.263G>T p.R88M | Missense Mutation (SNP) | VAF 263/372 reads (71%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); catalogued as rs1271712202; called by muse, mutect2, varscan2
- FAM155A | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs200446308, COSV101030649; called by muse, mutect2, varscan2
- FAM184A | c.1750C>T p.Q584* | Nonsense Mutation (SNP) | VAF 26/132 reads (20%) | catalogued as COSV58851303; called by muse, mutect2, varscan2
- FAT1 | c.4321C>T p.Q1441* | Nonsense Mutation (SNP) | VAF 69/111 reads (62%) | catalogued as COSV71674653; called by muse, mutect2, varscan2
- FLII | c.3501C>G p.F1167L | Missense Mutation (SNP) | VAF 71/403 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1349765136; called by muse, mutect2, varscan2
- FMOD | c.685G>T p.D229Y | Missense Mutation (SNP) | VAF 88/405 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61609844; called by muse, mutect2, varscan2
- FRMD4A | c.1965G>C p.Q655H | Missense Mutation (SNP) | VAF 117/329 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.724); catalogued as rs144479835; called by muse, mutect2, varscan2
- FSCB | c.2041G>A p.E681K | Missense Mutation (SNP) | VAF 147/390 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.412); catalogued as rs758200004, COSV100469996; called by muse, varscan2
- GADL1 | c.110G>C p.G37A | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as rs975104019; called by muse, mutect2
- GALNTL6 | c.249G>A p.G83= | Splice Region (SNP) | VAF 15/26 reads (58%) | catalogued as rs749645770, COSV71828212; called by muse, mutect2, varscan2
- GLI3 | c.4102C>T p.H1368Y | Missense Mutation (SNP) | VAF 281/815 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.04); catalogued as rs1379634152, COSV67890146; called by muse, mutect2, varscan2
- GPR149 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 312/659 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780542696, COSV67666784; called by muse, mutect2, varscan2
- HEATR5A | c.5212G>A p.E1738K | Missense Mutation (SNP) | VAF 52/419 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.3); catalogued as rs775214706; called by muse, mutect2, varscan2
- HIP1R | c.2608G>A p.E870K | Missense Mutation (SNP) | VAF 88/285 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs746458127; called by muse, mutect2, varscan2
- HSD17B14 | c.87C>T p.F29= | Splice Region (SNP) | VAF 40/166 reads (24%) | catalogued as COSV99052049; called by muse, varscan2
- IL11 | c.400G>C p.D134H | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs1017387351; called by muse, mutect2, varscan2
- IRF2BP2 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100784209; called by muse, mutect2, varscan2
- JCHAIN | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV54659377; called by muse, mutect2, varscan2
- KBTBD7 | c.1154C>T p.S385L | Missense Mutation (SNP) | VAF 206/357 reads (58%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65267008; called by muse, mutect2, varscan2
- KMT2C | c.10262G>C p.R3421T | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100069141; called by muse, mutect2, varscan2
- KMT5C | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 115/268 reads (43%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs760379110; called by muse, mutect2, varscan2
- KTN1 | c.1225C>T p.Q409* | Nonsense Mutation (SNP) | VAF 42/119 reads (35%) | catalogued as rs1341361683; called by muse, mutect2, varscan2
- LMBRD2 | c.1954C>T p.L652F | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.331); catalogued as COSV99683050; called by muse, mutect2, varscan2
- LRP11 | c.1381A>G p.I461V | Missense Mutation (SNP) | VAF 73/196 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs779952646; called by muse, mutect2, varscan2
- LTBP4 | c.4414G>A p.D1472N (on ENST00000308370 / NM_001042544.1; = p.D1435N on NM_003573.2) | Missense Mutation (SNP) | VAF 8/127 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.175); catalogued as rs1307462138, COSV52581996; called by muse, mutect2
- LYPD5 | c.169G>C p.E57Q (on ENST00000377950 / NM_001031749.3; = p.E14Q on NM_182573.2) | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV65020333; called by muse, mutect2, varscan2
- MADD | c.2156C>G p.S719C | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.195); catalogued as rs1013008661; called by muse, mutect2, varscan2
- MEGF8 | c.2534C>T p.S845L (on ENST00000251268 / NM_001271938.2; = p.S778L on NM_001410.3) | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1228508440, COSV52088756; called by muse, mutect2, varscan2
- MFSD14B | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 130/420 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1429492351; called by muse, mutect2, varscan2
- MMP12 | c.592G>A p.D198N | Missense Mutation (SNP) | VAF 96/184 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.362); catalogued as rs201174015; called by muse, varscan2
- NPC1 | c.2152G>T p.E718* | Nonsense Mutation (SNP) | VAF 49/210 reads (23%) | catalogued as COSV99341107; called by muse, mutect2, varscan2
- NUAK1 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 144/346 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs771843801, COSV54602649; called by muse, mutect2, varscan2
- OR13C3 | c.397T>C p.F133L | Missense Mutation (SNP) | VAF 129/438 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1262317106, COSV66165998; called by muse, mutect2, varscan2
- OR2T11 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 40/268 reads (15%) | catalogued as rs200110082, COSV58185445; called by muse, mutect2, varscan2
- OR5K4 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 45/82 reads (55%) | catalogued as COSV61584113; called by muse, mutect2, varscan2
- OR9G1 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as COSV56448152, COSV56451460; called by muse, mutect2, varscan2
- PCYOX1L | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 95/188 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs760744020; called by muse, mutect2, varscan2
- PDE4A | c.1420G>A p.D474N (on ENST00000380702 / NM_001111307.2; = p.D235N on NM_006202.3) | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53353843; called by muse, mutect2, varscan2
- PITHD1 | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.608); catalogued as rs373125988; called by muse, mutect2, varscan2
- PKD1L1 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs754774704; called by muse, mutect2
- PKD2L2 | c.241A>C p.I81L | Missense Mutation (SNP) | VAF 66/113 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.044); catalogued as COSV99296860; called by muse, mutect2, varscan2
- PLXNA4 | c.692C>T p.S231L | Missense Mutation (SNP) | VAF 47/477 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199931280, COSV58158937; called by muse, mutect2, varscan2
- PPFIA2 | c.338G>C p.C113S | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1305083515; called by muse, mutect2, varscan2
- PUSL1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs964146886; called by muse, mutect2, varscan2
- RP1 | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 93/234 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV55116133, COSV55123375; called by muse, mutect2, varscan2
- RUNX1T1 | c.1434G>A p.M478I (on ENST00000265814 / NM_001198628.1; = p.M451I on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/294 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV56143211, COSV56167643; called by muse, varscan2
- SCARA5 | c.1456G>A p.E486K | Missense Mutation (SNP) | VAF 72/345 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1554566382, COSV61571634; called by muse, mutect2, varscan2
- SHROOM4 | c.3570C>A p.H1190Q | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.806); catalogued as COSV56790091; called by muse, mutect2, varscan2
- SIPA1L3 | c.3934G>A p.D1312N | Missense Mutation (SNP) | VAF 128/433 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs143141927; called by muse, mutect2, varscan2
- SKOR2 | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.412); catalogued as rs1293682511; called by muse, mutect2, varscan2
- SLC12A4 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs200784647; called by muse, mutect2, varscan2
- SOAT1 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.981); catalogued as rs761415537; called by muse, mutect2, varscan2
- STC2 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 144/246 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.176); catalogued as rs769283117, COSV54180340; called by muse, mutect2, varscan2
- SULT1C3 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV61252394; called by muse, mutect2, varscan2
- SYNGR4 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 46/327 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs201450222; called by muse, mutect2, varscan2
- TCHH | c.4780G>C p.E1594Q | Missense Mutation (SNP) | VAF 101/510 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.72); catalogued as rs1557808509; called by mutect2, varscan2
- TCP1 | c.1615G>A p.D539N | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs201772698; called by muse, mutect2, varscan2
- TMEFF2 | c.746-1G>A p.X249_splice | Splice Site (SNP) | VAF 20/71 reads (28%) | catalogued as COSV99772668; called by muse, mutect2, varscan2
- TRIOBP | c.4947G>C p.Q1649H | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100730529; called by muse, mutect2, varscan2
- TSEN34 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 86/425 reads (20%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.642); catalogued as COSV55477573; called by muse, mutect2, varscan2
- TXNDC16 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 47/175 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201503108; called by muse, mutect2, varscan2
- TXNRD1 | c.381G>C p.Q127H (on ENST00000525566 / NM_001093771.3; = p.Q29H on NM_003330.4) | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.617); catalogued as rs756140350; called by muse, mutect2, varscan2
- USP42 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 98/333 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.385); catalogued as COSV60363645; called by muse, mutect2, varscan2
- WNK1 | c.3745C>G p.Q1249E (on ENST00000315939 / NM_018979.4; = p.Q1002E on NM_014823.3) | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60032767; called by muse, mutect2, varscan2
- XKR6 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 99/225 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.959); catalogued as rs777213893; called by muse, mutect2, varscan2
- XRCC3 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 133/408 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs759419858; called by muse, mutect2, varscan2
- ZNF385D | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 62/93 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs376185989; called by muse, mutect2, varscan2
- ZNF420 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs759789336; called by muse, mutect2, varscan2
- ZNF585A | c.855G>T p.L285F (on ENST00000292841 / NM_001288800.2; = p.L230F on NM_152655.3) | Missense Mutation (SNP) | VAF 74/223 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.516); catalogued as COSV99493679; called by muse, mutect2, varscan2
- ZNF626 | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 68/319 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.458); catalogued as COSV74129332; called by muse, mutect2, varscan2
- ZNF669 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 57/125 reads (46%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.982); catalogued as rs757399306; called by muse, mutect2, varscan2
- ZNF771 | c.216C>A p.F72L | Missense Mutation (SNP) | VAF 83/134 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60008091; called by muse, mutect2, varscan2
- ZNF98 | c.1121G>C p.G374A | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.294); catalogued as COSV63335857; called by muse, mutect2, varscan2
- ABCA12 | c.756C>G p.F252L | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKR7A2 | c.61C>A p.P21T | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AL645922.1 | c.908C>A p.S303Y | Missense Mutation (SNP) | VAF 87/393 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ANXA8L1 | c.732G>A p.M244I | Missense Mutation (SNP) | VAF 75/530 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, varscan2
- ARHGAP5 | c.1777A>G p.I593V | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- ARHGEF28 | c.1788C>T p.N596= | Splice Region (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- ARID4A | c.3178A>G p.I1060V | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, varscan2
- ARMC4 | c.2317C>G p.L773V | Missense Mutation (SNP) | VAF 51/369 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ASB12 | c.210G>A p.W70* | Nonsense Mutation (SNP) | VAF 29/245 reads (12%) | called by muse, mutect2, varscan2
- ASTN1 | c.1412G>C p.C471S | Missense Mutation (SNP) | VAF 76/345 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATMIN | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 87/155 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- ATP10A | c.565C>G p.P189A | Missense Mutation (SNP) | VAF 16/387 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2
- ATP2A1 | c.1056G>C p.K352N | Missense Mutation (SNP) | VAF 24/614 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- B4GALT3 | c.20A>C p.E7A | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- BRWD1 | c.6440C>A p.S2147* | Nonsense Mutation (SNP) | VAF 32/99 reads (32%) | called by muse, mutect2, varscan2
- C12orf40 | c.1919C>G p.A640G | Missense Mutation (SNP) | VAF 61/310 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C14orf93 | c.1000A>G p.I334V | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- C15orf48 | c.120G>A p.V40= | Splice Region (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- C6orf163 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- C8A | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 239/513 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA1C | c.6461G>A p.S2154N (on ENST00000399634 / NM_001167625.1; = p.S2083N on NM_000719.7) | Missense Mutation (SNP) | VAF 68/475 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASC3 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CCDC168 | c.20803C>T p.H6935Y | Missense Mutation (SNP) | VAF 32/207 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CCDC168 | c.14230G>C p.E4744Q | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- CCDC43 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CDCA7L | c.424C>G p.L142V | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CDHR1 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 75/528 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CDKN2A | c.155dup p.M52Ifs*68 | Frame Shift Ins (INS) | VAF 155/392 reads (40%) | called by mutect2, pindel, varscan2
- CENPV | c.305C>A p.S102* | Nonsense Mutation (SNP) | VAF 77/203 reads (38%) | called by muse, mutect2, varscan2
- CEP162 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- CEP290 | c.4660G>T p.E1554* | Nonsense Mutation (SNP) | VAF 87/276 reads (32%) | called by muse, mutect2, varscan2
- CFAP65 | c.904C>G p.Q302E | Missense Mutation (SNP) | VAF 78/277 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CIITA | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 251/399 reads (63%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- CLCN2 | c.2129G>A p.G710E | Missense Mutation (SNP) | VAF 230/822 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNMD | c.301T>A p.F101I | Missense Mutation (SNP) | VAF 159/258 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- COA5 | c.179C>G p.S60* | Nonsense Mutation (SNP) | VAF 24/163 reads (15%) | called by muse, mutect2, varscan2
- CPA5 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 164/1732 reads (9%) | called by muse, mutect2
- DAB2 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 127/385 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DCAF12L1 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 92/174 reads (53%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- DCAF5 | c.2527C>T p.H843Y | Missense Mutation (SNP) | VAF 99/317 reads (31%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- DERPC | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DLG4 | c.633G>C p.K211N (on ENST00000399506 / NM_001321075.3; = p.K254N on NM_001365.4) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DNAH1 | c.3175G>A p.E1059K | Missense Mutation (SNP) | VAF 115/185 reads (62%) | SIFT tolerated (0.15); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- DPP6 | c.841G>A p.E281K (on ENST00000377770 / NM_001364500.2; = p.E219K on NM_001936.5) | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- EFCAB8 | c.2628C>G p.I876M | Missense Mutation (SNP) | VAF 76/154 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ELN | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 285/705 reads (40%) | called by muse, mutect2, varscan2
- EPN2 | c.27G>C p.Q9H | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- EPOP | c.166C>G p.L56V | Missense Mutation (SNP) | VAF 94/277 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- EVC2 | c.1927G>T p.E643* | Nonsense Mutation (SNP) | VAF 114/224 reads (51%) | called by muse, mutect2, varscan2
- EYA2 | c.303C>G p.I101M | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EZH1 | c.36C>G p.I12M | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAM186B | c.1838C>T p.S613L | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- FAT2 | c.10580A>G p.Y3527C | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- FAT4 | c.13984G>T p.A4662S | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FBXL17 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- FBXO27 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 78/347 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FCRL6 | c.892C>G p.Q298E | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- FOXD3 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 88/322 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- FOXG1 | c.144C>G p.H48Q | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- FRMPD1 | c.1591G>A p.E531K | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2
- FRMPD1 | c.1840G>C p.E614Q | Missense Mutation (SNP) | VAF 75/268 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GABRA6 | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 35/154 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- GANAB | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GNAS | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 296/701 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- GOLGA8M | c.1023G>C p.E341D | Missense Mutation (SNP) | VAF 111/513 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- GON4L | c.4021G>C p.E1341Q | Missense Mutation (SNP) | VAF 224/637 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GPR179 | c.3043G>A p.G1015R (on ENST00000621958; = p.G1014R on NM_001004334.4) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- GRAMD1A | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 118/311 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GYS2 | c.1981G>T p.D661Y | Missense Mutation (SNP) | VAF 121/386 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- H1-5 | c.231G>C p.E77D | Missense Mutation (SNP) | VAF 175/505 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- H2AC8 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 107/486 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- H3C4 | c.152A>G p.E51G | Missense Mutation (SNP) | VAF 136/368 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- H3C4 | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 139/366 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- HMGXB4 | c.1732G>A p.E578K | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- HOXB8 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 107/388 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGF2R | c.2876C>T p.S959F | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV1D-37 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0.01); PolyPhen benign (0.352); called by mutect2, varscan2
- IL13RA1 | c.248G>T p.R83L | Missense Mutation (SNP) | VAF 59/108 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- INSL5 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IQANK1 | c.137G>C p.R46T | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KATNAL2 | c.676T>C p.F226L (on ENST00000356157 / NM_001353899.1; = p.F154L on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- KIFAP3 | c.1624C>T p.L542F | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); called by muse, mutect2
- KMT2D | c.3190dup p.V1064Gfs*4 | Frame Shift Ins (INS) | VAF 106/268 reads (40%) | called by mutect2, pindel, varscan2
- LY75 | c.526G>C p.D176H | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MACF1 | c.2569C>T p.Q857* | Nonsense Mutation (SNP) | VAF 39/229 reads (17%) | called by muse, mutect2, varscan2
- MAP3K4 | c.2149C>G p.Q717E | Missense Mutation (SNP) | VAF 60/330 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MARS2 | c.515C>T p.S172F | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MBD3L3 | c.317C>A p.S106* | Nonsense Mutation (SNP) | VAF 64/770 reads (8%) | called by muse, mutect2, varscan2
- MIA2 | c.1348C>T p.Q450* | Nonsense Mutation (SNP) | VAF 20/71 reads (28%) | called by muse, mutect2, varscan2
- MICAL3 | c.1058C>G p.S353C | Missense Mutation (SNP) | VAF 87/430 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- NAA30 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 103/366 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBAS | c.6793G>T p.E2265* | Nonsense Mutation (SNP) | VAF 72/284 reads (25%) | called by muse, mutect2, varscan2
- NCALD | c.267G>C p.L89F | Missense Mutation (SNP) | VAF 57/404 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR4D5 | c.391C>G p.H131D | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- OVOL1 | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 122/242 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P3H2 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- PCLO | c.11456G>A p.R3819K | Missense Mutation (SNP) | VAF 74/270 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PEAK3 | c.1160C>T p.S387L | Missense Mutation (SNP) | VAF 66/257 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- PLPPR3 | c.2095G>A p.E699K (on ENST00000520876 / NM_001270366.2; = p.E727K on NM_024888.2) | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- POGZ | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 81/385 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PPP2CB | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 74/196 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRRC2C | c.5282C>T p.S1761L (on ENST00000367742; = p.S1759L on NM_015172.4) | Missense Mutation (SNP) | VAF 115/277 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PRXL2A | c.232A>G p.M78V | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- RELCH | c.2017G>A p.D673N | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- REPIN1 | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- RHBDF2 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 136/445 reads (31%) | called by muse, mutect2, varscan2
- RNF169 | c.740C>G p.S247* | Nonsense Mutation (SNP) | VAF 26/115 reads (23%) | called by muse, mutect2, varscan2
- RPS10-NUDT3 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 56/307 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- RSPH3 | c.1515G>C p.Q505H (on ENST00000252655; = p.Q363H on NM_031924.8) | Missense Mutation (SNP) | VAF 44/356 reads (12%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2
- SAMSN1 | c.973T>C p.S325P | Missense Mutation (SNP) | VAF 114/305 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- SART1 | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 205/378 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- SEC23A | c.1333C>T p.Q445* | Nonsense Mutation (SNP) | VAF 67/261 reads (26%) | called by muse, mutect2, varscan2
- SH2D4A | c.1014G>C p.Q338H | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- SHB | c.329G>C p.C110S | Missense Mutation (SNP) | VAF 90/321 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SNTG2 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPAG5 | c.1474G>A p.E492K | Missense Mutation (SNP) | VAF 61/244 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- STIP1 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- TBC1D25 | c.435dup p.G146Wfs*8 | Frame Shift Ins (INS) | VAF 118/328 reads (36%) | called by mutect2, pindel, varscan2
- TBC1D9B | c.2664C>G p.F888L | Missense Mutation (SNP) | VAF 60/241 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, varscan2
- TCP11L2 | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 69/398 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TDRD10 | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- TDRD6 | c.4400G>A p.G1467E | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM121B | c.863C>A p.A288E | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TMEM247 | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 51/292 reads (17%) | called by muse, varscan2
- TMPRSS9 | c.1727C>T p.A576V (on ENST00000648592; = p.A542V on NM_182973.2) | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TP53 | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 71/426 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- TP53 | c.685_695del p.C229Pfs*7 | Frame Shift Del (DEL) | VAF 101/406 reads (25%) | called by mutect2, pindel, varscan2
- TPO | c.1236_1237del p.E413Afs*58 | Frame Shift Del (DEL) | VAF 83/388 reads (21%) | called by pindel, varscan2
- TRAPPC9 | c.2262del p.V755Ffs*13 | Frame Shift Del (DEL) | VAF 107/392 reads (27%) | called by mutect2, pindel, varscan2
- TRAPPC9 | c.1645C>A p.P549T | Missense Mutation (SNP) | VAF 186/591 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- TRAV8-4 | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 41/260 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTN | c.98449T>A p.Y32817N (on ENST00000591111; = p.Y25393N on NM_003319.4) | Missense Mutation (SNP) | VAF 54/188 reads (29%) | PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- TULP3 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TXLNA | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UGT3A1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 83/301 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- USO1 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- VEPH1 | c.2300G>A p.S767N | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.376); called by mutect2, varscan2
- VN1R4 | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- VPS13C | c.1270G>A p.E424K (on ENST00000644861 / NM_020821.3; = p.E381K on NM_017684.5) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- VWA8 | c.5257G>A p.E1753K | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- WDFY4 | c.8003G>A p.R2668K | Missense Mutation (SNP) | VAF 17/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XXYLT1 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 81/177 reads (46%) | called by muse, mutect2, varscan2
- XYLB | c.262C>G p.Q88E | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZBTB14 | c.298G>A p.V100M | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF227 | c.518G>A p.R173K | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF385C | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF610 | c.513C>A p.F171L | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF671 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 39/255 reads (15%) | SIFT tolerated (0.93); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZNF98 | c.583T>C p.S195P | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- AC005324.2 | c.1362C>T p.F454= | Silent (SNP) | VAF 51/154 reads (33%) | called by muse, mutect2, varscan2
- ACP4 | c.810C>T p.F270= | Silent (SNP) | VAF 163/384 reads (42%) | catalogued as rs778731422, COSV54516414; called by muse, mutect2, varscan2
- ADAMTS2 | c.3033C>T p.I1011= | Silent (SNP) | VAF 66/385 reads (17%) | catalogued as COSV52375459; called by muse, mutect2, varscan2
- AEBP1 | c.2895G>A p.K965= | Silent (SNP) | VAF 23/405 reads (6%) | called by muse, mutect2
- AHNAK | c.1287G>C p.L429= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV57210906; called by muse, mutect2
- ATF7IP | c.1459T>C p.L487= | Silent (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- ATP2A2 | c.54C>T p.V18= | Silent (SNP) | VAF 64/184 reads (35%) | catalogued as COSV58043717; called by muse, mutect2, varscan2
- ATP8B2 | c.2145G>A p.V715= (on ENST00000672630; = p.V682= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 37/167 reads (22%) | called by muse, mutect2, varscan2
- BCAT2 | c.918G>A p.Q306= | Silent (SNP) | VAF 34/195 reads (17%) | called by muse, mutect2, varscan2
- C7orf50 | c.363G>A p.T121= | Silent (SNP) | VAF 29/240 reads (12%) | catalogued as rs375450091; called by muse, mutect2, varscan2
- CAP1 | c.609C>T p.T203= | Silent (SNP) | VAF 64/220 reads (29%) | catalogued as rs774079016; called by muse, mutect2, varscan2
- CARD6 | c.2826C>T p.F942= | Silent (SNP) | VAF 113/400 reads (28%) | called by muse, mutect2, varscan2
- CCDC39 | c.1809C>T p.I603= | Silent (SNP) | VAF 17/146 reads (12%) | called by muse, mutect2, varscan2
- CEP128 | c.1116G>A p.L372= | Silent (SNP) | VAF 128/319 reads (40%) | catalogued as rs1226215147, COSV53677350; called by muse, mutect2, varscan2
- CFAP161 | c.600C>T p.P200= | Silent (SNP) | VAF 46/72 reads (64%) | catalogued as rs751163987; called by muse, mutect2, varscan2
- CHAT | c.1104C>T p.L368= | Silent (SNP) | VAF 74/521 reads (14%) | catalogued as rs551349781, COSV60319800; called by muse, mutect2, varscan2
- CNTNAP5 | c.2910G>A p.G970= | Silent (SNP) | VAF 46/180 reads (26%) | called by muse, mutect2, varscan2
- CRLF3 | c.501G>A p.V167= | Silent (SNP) | VAF 28/187 reads (15%) | catalogued as rs998043777, COSV100158291; called by muse, mutect2, varscan2
- CRYBG1 | c.712C>T p.L238= | Silent (SNP) | VAF 41/74 reads (55%) | called by muse, mutect2, varscan2
- DACT2 | c.1194C>A p.A398= | Silent (SNP) | VAF 33/149 reads (22%) | called by muse, mutect2, varscan2
- DNAH2 | c.7581G>A p.L2527= | Silent (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- DNER | c.258C>T p.I86= | Silent (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2
- EIF4G3 | c.1944C>T p.I648= | Silent (SNP) | VAF 24/105 reads (23%) | called by muse, mutect2, varscan2
- ERBB4 | c.1692T>C p.D564= | Silent (SNP) | VAF 72/287 reads (25%) | called by muse, mutect2, varscan2
- ERICH3 | c.1869G>A p.L623= | Silent (SNP) | VAF 63/308 reads (20%) | called by muse, mutect2, varscan2
- FAM186B | c.1677C>T p.I559= | Silent (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- FAM47C | c.375G>A p.L125= | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as rs142090974; called by muse, mutect2, varscan2
- FBXL16 | c.678G>C p.S226= | Silent (SNP) | VAF 68/112 reads (61%) | catalogued as rs1467353885, COSV100178914, COSV60964348, COSV60965613; called by muse, mutect2, varscan2
- GJA10 | c.225C>T p.I75= | Silent (SNP) | VAF 81/167 reads (49%) | called by muse, mutect2, varscan2
- GRINA | c.141C>T p.F47= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV57297870; called by muse, mutect2, varscan2
- GRIP1 | c.2223G>A p.Q741= (on ENST00000359742 / NM_001379345.1; = p.Q689= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 93/320 reads (29%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.733C>T p.L245= | Silent (SNP) | VAF 26/137 reads (19%) | called by muse, mutect2, varscan2
- GTF2IRD2B | c.2460G>A p.L820= | Silent (SNP) | VAF 30/1018 reads (3%) | called by muse, mutect2
- H4C2 | c.198G>A p.V66= | Silent (SNP) | VAF 47/323 reads (15%) | catalogued as rs192365376, COSV55140871, COSV99774872, COSV99775131; called by muse, mutect2, varscan2
- IGBP1P2 | c.144C>T p.L48= | Silent (SNP) | VAF 59/197 reads (30%) | catalogued as rs1420268734; called by muse, mutect2, varscan2
- IGFBP1 | c.120C>T p.L40= | Silent (SNP) | VAF 138/769 reads (18%) | called by muse, mutect2, varscan2
- IGFN1 | c.2613G>A p.Q871= (on ENST00000295591 / NM_001367841.1; = p.Q3328= on NM_001164586.2) | Silent (SNP) | VAF 49/252 reads (19%) | catalogued as COSV55172720, COSV55173577; called by muse, mutect2, varscan2
- ITFG2 | c.522C>G p.L174= | Silent (SNP) | VAF 38/98 reads (39%) | called by muse, mutect2, varscan2
- KIF11 | c.2157C>A p.S719= | Silent (SNP) | VAF 18/298 reads (6%) | called by muse, mutect2
- KIF7 | c.1374C>T p.S458= | Silent (SNP) | VAF 111/203 reads (55%) | catalogued as rs1188752790; called by muse, mutect2, varscan2
- LAMP3 | c.966C>T p.I322= | Silent (SNP) | VAF 26/220 reads (12%) | called by muse, mutect2, varscan2
- LRRC45 | c.165G>T p.P55= | Silent (SNP) | VAF 72/478 reads (15%) | called by muse, mutect2, varscan2
- MADD | c.1545C>G p.L515= | Silent (SNP) | VAF 112/461 reads (24%) | called by muse, mutect2, varscan2
- MED16 | c.1746G>A p.E582= | Silent (SNP) | VAF 53/190 reads (28%) | called by muse, mutect2, varscan2
- MROH1 | c.1452C>G p.L484= | Silent (SNP) | VAF 262/825 reads (32%) | called by muse, mutect2, varscan2
- MYBPC1 | c.387C>T p.I129= (on ENST00000550270 / NM_206820.2; = p.I154= on NM_002465.4) | Silent (SNP) | VAF 119/320 reads (37%) | catalogued as COSV62258846; called by mutect2, varscan2
- NECTIN4 | c.399C>T p.P133= | Silent (SNP) | VAF 68/282 reads (24%) | catalogued as rs746014173; called by muse, mutect2, varscan2
- NIBAN1 | c.747C>T p.L249= | Silent (SNP) | VAF 72/176 reads (41%) | called by muse, mutect2, varscan2
- NID1 | c.2601A>G p.R867= | Silent (SNP) | VAF 78/425 reads (18%) | called by muse, mutect2, varscan2
- NLE1 | c.138C>G p.L46= | Silent (SNP) | VAF 53/246 reads (22%) | catalogued as COSV100681018; called by muse, mutect2, varscan2
- NOLC1 | c.1665G>A p.Q555= | Silent (SNP) | VAF 94/232 reads (41%) | called by muse, mutect2, varscan2
- NUP210 | c.1716C>A p.T572= | Silent (SNP) | VAF 152/265 reads (57%) | called by muse, mutect2, varscan2
- OR2AJ1 | c.84C>T p.F28= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- OSGIN2 | c.1264C>T p.L422= | Silent (SNP) | VAF 89/250 reads (36%) | called by muse, mutect2, varscan2
- PAK2 | c.717C>T p.I239= | Silent (SNP) | VAF 20/180 reads (11%) | catalogued as rs144419620; called by muse, mutect2, varscan2
- PLA2G4C | c.1593G>A p.P531= | Silent (SNP) | VAF 37/187 reads (20%) | catalogued as rs779631342, COSV53153536; called by muse, mutect2, varscan2
- PLEKHG3 | c.1197C>G p.L399= (on ENST00000394691; = p.L455= on NM_001308147.2) | Silent (SNP) | VAF 58/421 reads (14%) | called by muse, mutect2, varscan2
- PLSCR2 | c.375G>A p.Q125= (on ENST00000497985 / NM_001199978.1; = p.Q52= on NM_020359.2) | Silent (SNP) | VAF 65/439 reads (15%) | called by muse, mutect2, varscan2
- PSMC6 | c.108C>T p.I36= (on ENST00000612399; = p.I22= on NM_002806.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 105/353 reads (30%) | called by muse, mutect2, varscan2
- QPRT | c.586C>T p.L196= | Silent (SNP) | VAF 62/97 reads (64%) | catalogued as COSV54879211; called by muse, mutect2, varscan2
- RANBP17 | c.3108C>T p.A1036= | Silent (SNP) | VAF 89/179 reads (50%) | called by muse, mutect2, varscan2
- RUNX1 | c.942C>T p.S314= (on ENST00000344691 / NM_001001890.3; = p.S341= on NM_001754.5) | Silent (SNP) | VAF 71/215 reads (33%) | called by muse, mutect2, varscan2
- SETD1A | c.4287C>T p.D1429= | Silent (SNP) | VAF 84/170 reads (49%) | called by muse, varscan2
- SHB | c.663C>G p.L221= | Silent (SNP) | VAF 45/164 reads (27%) | called by muse, mutect2, varscan2
- SLC7A7 | c.213C>T p.L71= | Silent (SNP) | VAF 38/202 reads (19%) | called by muse, mutect2, varscan2
- SLMAP | c.2193C>T p.I731= (on ENST00000428312 / NM_001377924.1; = p.I344= on NM_001304422.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 48/202 reads (24%) | catalogued as rs772017948; called by muse, mutect2, varscan2
- SMYD1 | c.1472G>A p.*491= | Silent (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- SPTBN4 | c.4470G>A p.Q1490= | Silent (SNP) | VAF 95/432 reads (22%) | called by muse, mutect2, varscan2
- STX5 | c.414C>T p.I138= | Silent (SNP) | VAF 46/82 reads (56%) | catalogued as rs1421740614; called by muse, mutect2, varscan2
- TRMT12 | c.1035G>A p.K345= | Silent (SNP) | VAF 49/296 reads (17%) | called by muse, mutect2, varscan2
- TRPV5 | c.723C>T p.L241= | Silent (SNP) | VAF 60/160 reads (38%) | called by muse, mutect2, varscan2
- TTC16 | c.2034G>A p.Q678= | Silent (SNP) | VAF 90/490 reads (18%) | catalogued as COSV60161637; called by muse, varscan2
- TYK2 | c.1215G>C p.L405= | Silent (SNP) | VAF 192/887 reads (22%) | called by muse, mutect2, varscan2
- UBB | c.447G>C p.L149= | Silent (SNP) | VAF 254/736 reads (35%) | called by muse, varscan2
- UBE2G1 | c.201C>A p.L67= | Silent (SNP) | VAF 27/201 reads (13%) | called by muse, mutect2, varscan2
- VGLL1 | c.606C>T p.L202= | Silent (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- WDR27 | c.72G>A p.L24= | Silent (SNP) | VAF 21/151 reads (14%) | called by muse, mutect2, varscan2
- WDR97 | c.3114G>A p.L1038= | Silent (SNP) | VAF 129/377 reads (34%) | catalogued as rs1360149258; called by muse, mutect2, varscan2
- ZNF229 | c.1389T>C p.C463= | Silent (SNP) | VAF 64/341 reads (19%) | called by muse, mutect2, varscan2
- ZNF564 | c.702C>T p.F234= | Silent (SNP) | VAF 48/296 reads (16%) | catalogued as rs749170416; called by muse, mutect2, varscan2
- ZNF641 | c.672G>A p.E224= | Silent (SNP) | VAF 51/89 reads (57%) | called by muse, mutect2, varscan2
- ZNF852 | c.846G>A p.R282= | Silent (SNP) | VAF 11/149 reads (7%) | catalogued as rs191114956; called by muse, mutect2
- ABI3BP | c.1063+759C>T | Intron (SNP) | VAF 39/115 reads (34%) | catalogued as COSV52532275, COSV52536306; called by muse, mutect2, varscan2
- AC011410.1 | n.405G>A | RNA (SNP) | VAF 85/181 reads (47%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-8799G>A | Intron (SNP) | VAF 94/357 reads (26%) | catalogued as rs782229291, COSV73145128; called by muse, mutect2, varscan2
- ACTR10 | c.151-779C>T | Intron (SNP) | VAF 10/33 reads (30%) | called by muse, mutect2, varscan2
- AKIRIN1 | c.*105G>C | 3'UTR (SNP) | VAF 13/304 reads (4%) | called by muse, mutect2
- AL132796.2 | n.501C>T | RNA (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- ASCC2 | c.541+361C>G | Intron (SNP) | VAF 34/184 reads (18%) | called by muse, mutect2, varscan2
- BLACE | n.1609_1615dup | RNA (INS) | VAF 38/121 reads (31%) | called by mutect2, varscan2
- C6orf201 | c.285-6413G>T | Intron (SNP) | VAF 45/223 reads (20%) | called by muse, mutect2, varscan2
- CABYR | c.*17-133G>A | Intron (SNP) | VAF 65/263 reads (25%) | called by muse, mutect2, varscan2
- CASTOR3 | n.274G>A | RNA (SNP) | VAF 62/606 reads (10%) | called by muse, mutect2, varscan2
- CCDC88C | c.4442-2196C>T | Intron (SNP) | VAF 86/245 reads (35%) | called by muse, mutect2, varscan2
- CCNE1 | c.-20C>T | 5'UTR (SNP) | VAF 25/96 reads (26%) | called by muse, mutect2, varscan2
- CDCA7L | c.-24G>A | 5'UTR (SNP) | VAF 85/234 reads (36%) | called by muse, mutect2, varscan2
- CENPP | c.*5016G>A | 3'UTR (SNP) | VAF 27/100 reads (27%) | catalogued as rs776578369; called by muse, mutect2, varscan2
- CEP19 | c.-2G>A | 5'UTR (SNP) | VAF 43/141 reads (30%) | called by muse, mutect2
- CFAP47 | c.5536-421T>G | Intron (SNP) | VAF 30/70 reads (43%) | called by muse, varscan2
- CLASP1 | c.2734-745C>T | Intron (SNP) | VAF 17/92 reads (18%) | called by muse, mutect2, varscan2
- CLRN1 | c.*1167G>C | 3'UTR (SNP) | VAF 65/523 reads (12%) | called by muse, mutect2, varscan2
- CTHRC1 | c.-69G>A | 5'UTR (SNP) | VAF 175/453 reads (39%) | called by muse, mutect2, varscan2
- DST | c.4296+4332G>A | Intron (SNP) | VAF 36/212 reads (17%) | called by muse, mutect2, varscan2
- EDRF1 | c.2815-45A>G | Intron (SNP) | VAF 69/179 reads (39%) | called by muse, mutect2, varscan2
- EPOR | c.251+91T>G | Intron (SNP) | VAF 21/476 reads (4%) | called by muse, mutect2
- ERLIN2 | chr8:37735960 C>G | 5'Flank (SNP) | VAF 9/36 reads (25%) | called by muse, mutect2, varscan2
- FAM90A27P | n.83G>A | RNA (SNP) | VAF 94/219 reads (43%) | catalogued as rs1463144438; called by muse, mutect2, varscan2
- FBXW7 | c.501+29051A>T | Intron (SNP) | VAF 31/57 reads (54%) | called by muse, mutect2, varscan2
- GGA3 | chr17:75261626 G>A | 5'Flank (SNP) | VAF 9/43 reads (21%) | catalogued as rs762143791; called by muse, mutect2, varscan2
- GUSBP4 | n.338G>A | RNA (SNP) | VAF 297/684 reads (43%) | catalogued as rs767851845; called by muse, mutect2, varscan2
- HSP90AA4P | n.1660G>A | RNA (SNP) | VAF 106/226 reads (47%) | called by muse, mutect2, varscan2
- LATS1 | c.349-1912C>T | Intron (SNP) | VAF 23/157 reads (15%) | called by muse, mutect2, varscan2
- LGALS9 | c.131+16G>C | Intron (SNP) | VAF 59/270 reads (22%) | called by muse, varscan2
- LHX9 | chr1:197916687 G>A | 5'Flank (SNP) | VAF 103/287 reads (36%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-11669G>A | Intron (SNP) | VAF 53/142 reads (37%) | catalogued as rs1338453067; called by muse, mutect2, varscan2
- MAD2L1BP | c.-5C>T | 5'UTR (SNP) | VAF 155/375 reads (41%) | catalogued as rs961631656; called by muse, mutect2, varscan2
- MAPKAPK5 | c.36+21C>G | Intron (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- MEIS3 | c.*29G>A | 3'UTR (SNP) | VAF 22/104 reads (21%) | catalogued as rs1182117469; called by muse, mutect2, varscan2
- MIR125B1 | n.20G>C | RNA (SNP) | VAF 16/61 reads (26%) | called by muse, mutect2, varscan2
- MPRIP | c.2164-3929G>A | Intron (SNP) | VAF 93/555 reads (17%) | called by muse, mutect2, varscan2
- MTCL1 | c.2968-3166G>A | Intron (SNP) | VAF 85/229 reads (37%) | catalogued as COSV60406250; called by muse, mutect2, varscan2
- MYADML | n.804G>A | RNA (SNP) | VAF 86/578 reads (15%) | catalogued as rs779643976; called by muse, mutect2, varscan2
- NRXN1 | c.3365-109917C>T | Intron (SNP) | VAF 36/132 reads (27%) | called by muse, mutect2, varscan2
- PDGFRA | c.759+24T>A | Intron (SNP) | VAF 144/280 reads (51%) | called by muse, varscan2
- PDHB | c.934+11G>C | Intron (SNP) | VAF 75/128 reads (59%) | catalogued as COSV100240081; called by muse, mutect2, varscan2
- PDIA3P1 | n.1289C>G | RNA (SNP) | VAF 88/423 reads (21%) | called by muse, mutect2, varscan2
- PI4KAP2 | chr22:21476694 C>A | 3'Flank (SNP) | VAF 30/40 reads (75%) | called by mutect2, varscan2
- PMP22 | c.78+48C>T | Intron (SNP) | VAF 145/470 reads (31%) | called by muse, mutect2, varscan2
- POLR1C | c.656-39G>C | Intron (SNP) | VAF 126/334 reads (38%) | called by muse, mutect2, varscan2
- RNF170 | chr8:42896636 C>T | 5'Flank (SNP) | VAF 52/182 reads (29%) | called by muse, mutect2, varscan2
- RPGRIP1L | c.1244-43G>A | Intron (SNP) | VAF 61/92 reads (66%) | called by muse, mutect2, varscan2
- RPL35 | c.3+10G>A | Intron (SNP) | VAF 76/270 reads (28%) | catalogued as rs1260417599; called by muse, varscan2
- RPS7 | c.147+37G>A | Intron (SNP) | VAF 46/170 reads (27%) | catalogued as rs1455302536; called by muse, mutect2, varscan2
- SART1 | c.982-40G>A | Intron (SNP) | VAF 187/331 reads (56%) | called by muse, mutect2, varscan2
- SREK1 | chr5:66144474 A>T | 5'Flank (SNP) | VAF 85/160 reads (53%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*2829T>G | 3'UTR (SNP) | VAF 31/172 reads (18%) | called by muse, mutect2, varscan2
- TMEM159 | c.97-3551C>T | Intron (SNP) | VAF 32/161 reads (20%) | called by muse, mutect2, varscan2
- TMEM99 | n.1074C>G | RNA (SNP) | VAF 27/83 reads (33%) | catalogued as COSV56983027; called by muse, mutect2, varscan2
- TNPO2 | c.-13-358C>T | Intron (SNP) | VAF 38/84 reads (45%) | catalogued as COSV63509647; called by muse, varscan2
- TPM2 | c.*29C>G | 3'UTR (SNP) | VAF 119/233 reads (51%) | called by muse, mutect2, varscan2
- TTN | c.35374+520G>C | Intron (SNP) | VAF 11/43 reads (26%) | catalogued as COSV104413425; called by muse, mutect2
- UMODL1 | c.1187-426T>G | Intron (SNP) | VAF 19/164 reads (12%) | called by muse, mutect2, varscan2
- ZNF24 | c.568+812A>T | Intron (SNP) | VAF 17/64 reads (27%) | called by muse, mutect2, varscan2
